Gene-level copy-number profile of tumor specimen TCGA-AJ-A2QK-01A from TCGA case TCGA-AJ-A2QK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.6 years (23,945 days).
Specimen TCGA-AJ-A2QK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.bb422231-40cd-47b8-95e4-2e4da788bf83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A2QK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e19be1a1-f8d6-4b09-9340-1b2ae6384a07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,664; copy number 2: 37,172; copy number 3: 1,692; copy number 4: 156; copy number 6: 129; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A2QK-01A-11D-A18N-01): tumor purity 0.65, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,425,690–73,142,318, 129 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr16:59,540,126–59,540,266, 1 gene, copy number 12: RNU4-58P.

Autosomal genes at a single copy (total copy number 1): 18,243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
